CPTAC case C223491 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/afa872d2-3d2a-475e-b9f5-c551bc6cc695

Demographics
Sex at birth: female; Age at index: 67 years; Vital status: Dead; Days to death: 850 days (2.3 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Cerebrum; Last known disease status: With tumor; Days to last known disease status: 850 days (2.3 years); Progression or recurrence: yes; Days to recurrence: 335 days; Sites of involvement: Brain, Cerebrum; Tumor focality: Unifocal.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0; Cigarettes per day: 0; Alcohol history: Yes.

Biospecimens (5 samples)
- Samples 1104812, 1105191, SM-JU34O, SM-JU351 (4 with the same recorded description): Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Biospecimen laterality: Right; Preservation method: Snap Frozen.
- Sample 1105289: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
